Somatic mutation profile of tumor specimen TCGA-B0-5695-01A (aliquot TCGA-B0-5695-01A-11D-1534-10) from TCGA case TCGA-B0-5695, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.1 years (22,320 days).
Specimen TCGA-B0-5695-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ed0ba2b-6095-4e1c-a562-ddc77e592dc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5695-11A (Solid Tissue Normal), aliquot TCGA-B0-5695-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebad35c1-d47c-4952-a072-756ff06d64c6

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 3, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.3031C>A p.P1011T (on ENST00000326724 / NM_001080395.3; = p.P908T on NM_004920.2) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV58373784; called by muse, varscan2
- ANKRD7 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 135/373 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54556678; called by muse, mutect2, varscan2
- C2CD5 | c.2801del p.L934* | Frame Shift Del (DEL) | VAF 65/242 reads (27%) | catalogued as COSV61728160; called by mutect2, pindel, varscan2
- CA11 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV50034391; called by muse, mutect2
- CACYBP | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 31/182 reads (17%) | catalogued as COSV62881701; called by muse, mutect2, varscan2
- CCDC73 | c.1471T>A p.S491T | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV58805552; called by muse, mutect2, varscan2
- CDADC1 | c.1199A>C p.E400A | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV51914011; called by muse, mutect2
- CLIC6 | c.1703C>G p.S568C (on ENST00000360731 / NM_001317009.2; = p.S550C on NM_053277.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV62449771; called by muse, mutect2, varscan2
- CLN8 | c.620T>A p.L207Q | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1510945, COSV58671597; called by muse, mutect2, varscan2
- EPS8 | c.1434G>C p.E478D | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV55537286; called by muse, mutect2, varscan2
- FBN2 | c.3488A>T p.E1163V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV52547656; called by muse, mutect2, varscan2
- GBGT1 | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV64410678; called by muse, mutect2, varscan2
- GNPTAB | c.1128T>A p.N376K | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV68450009; called by muse, mutect2, varscan2
- GPRASP2 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | catalogued as COSV59992642; called by muse, mutect2
- HERC2 | c.11627G>T p.R3876M | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55352659; called by muse, mutect2, varscan2
- HSD3B1 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.869); catalogued as COSV52492423; called by muse, mutect2, varscan2
- HVCN1 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV54374355; called by muse, mutect2, varscan2
- IP6K2 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV60795580; called by muse, mutect2, varscan2
- IZUMO1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 67/162 reads (41%) | catalogued as COSV59570274; called by muse, mutect2, varscan2
- KIF1B | c.3979G>A p.E1327K (on ENST00000377086 / NM_001365952.1; = p.E1281K on NM_015074.3) | Missense Mutation (SNP) | VAF 191/562 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV55817107; called by muse, mutect2, varscan2
- LAMA2 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV70356158; called by muse, mutect2, varscan2
- MGA | c.2974del p.Q992Rfs*2 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as COSV54959965; called by mutect2, pindel, varscan2
- OSBPL5 | c.2533C>T p.R845W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs150730024; called by muse, mutect2, varscan2
- PAPOLG | c.1671A>T p.E557D | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53186109; called by muse, mutect2, varscan2
- PFKL | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as COSV62465764; called by muse, mutect2, varscan2
- PLXDC2 | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV65919296, COSV65923770; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV51489588; called by muse, mutect2, varscan2
- RB1CC1 | c.900T>A p.D300E | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as COSV50278785; called by muse, mutect2, varscan2
- ROS1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV63862324; called by muse, mutect2
- SF3A1 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV53171576; called by muse, mutect2, varscan2
- SMC3 | c.2468G>C p.G823A | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100700029, COSV62422645; called by muse, mutect2
- SMC3 | c.2470A>T p.I824F | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV62422652; called by muse, mutect2
- SPEN | c.7325A>T p.E2442V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV65367946; called by muse, mutect2, varscan2
- ST3GAL5 | c.844C>G p.L282V (on ENST00000377332; = p.L322V on NM_003896.4) | Missense Mutation (SNP) | VAF 120/333 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60387226; called by muse, mutect2
- THOC2 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 129/518 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV55552708, COSV55556701; called by muse, mutect2, varscan2
- TP73 | c.146T>C p.M49T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60706595; called by muse, mutect2, varscan2
- TRIM5 | c.536C>G p.T179S | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs1360440198, COSV59902389; called by muse, mutect2, varscan2
- TRIP11 | c.4192C>A p.L1398I | Missense Mutation (SNP) | VAF 126/374 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV50967287; called by muse, varscan2
- TTC26 | c.234G>A p.E78= | Splice Region (SNP) | VAF 182/474 reads (38%) | catalogued as COSV58274846; called by muse, mutect2, varscan2
- TYW1 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 142/428 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62756681; called by muse, varscan2
- USH1C | c.819+2T>G p.X273_splice | Splice Site (SNP) | VAF 26/83 reads (31%) | catalogued as COSV50039276; called by muse, mutect2, varscan2
- VHL | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 49/96 reads (51%) | catalogued as CD093920, CM961430, COSV56545604, COSV56548401; called by muse, mutect2, varscan2
- VPS13B | c.9752C>G p.P3251R | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV62158888; called by muse, mutect2, varscan2
- YTHDF1 | c.1274T>C p.F425S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64833990; called by muse, varscan2
- ZKSCAN1 | c.1463C>G p.P488R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60875924; called by muse, mutect2
- ZNF101 | c.1242A>T p.R414S | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV58910154; called by muse, mutect2
- AARS1 | c.1565del p.G522Afs*28 | Frame Shift Del (DEL) | VAF 36/112 reads (32%) | called by mutect2, pindel, varscan2
- CLTC | c.2292+2dup p.X764_splice | Splice Site (INS) | VAF 123/370 reads (33%) | called by mutect2, pindel, varscan2
- MAP4K3 | c.358del p.T120Hfs*18 | Frame Shift Del (DEL) | VAF 150/467 reads (32%) | called by mutect2, pindel, varscan2
- PBRM1 | c.715-4_727del p.X239_splice | Splice Site (DEL) | VAF 124/392 reads (32%) | called by mutect2, pindel, varscan2
- ATIC | c.1497T>C p.I499= | Silent (SNP) | VAF 101/270 reads (37%) | catalogued as COSV52695596; called by muse, mutect2
- FGL2 | c.33A>G p.S11= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV50386244; called by muse, mutect2, varscan2
- FOXK1 | c.579C>T p.P193= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV61069100; called by muse, mutect2, varscan2
- IGHV1-3 | c.282C>T p.S94= | Silent (SNP) | VAF 58/188 reads (31%) | catalogued as rs113102957; called by muse, mutect2, varscan2
- LIPE | c.474G>A p.A158= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as rs1350029405, COSV54925651; called by muse, mutect2, varscan2
- LMBR1 | c.1074T>C p.L358= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV62223714; called by muse, mutect2, varscan2
- LRGUK | c.45T>C p.S15= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV53644402; called by muse, mutect2, varscan2
- MKS1 | c.1386A>G p.V462= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV56599638; called by muse, mutect2
- NEDD4 | c.441T>C p.C147= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs1311535131, COSV59067250; called by muse, mutect2, varscan2
- PTPRD | c.2007T>A p.T669= | Silent (SNP) | VAF 122/308 reads (40%) | catalogued as rs758916661, COSV61985485; called by muse, mutect2, varscan2
- RSPH3 | c.267T>A p.G89= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as COSV51924975; called by muse, mutect2, varscan2
- TRIP11 | c.4191G>A p.Q1397= | Silent (SNP) | VAF 131/390 reads (34%) | catalogued as COSV50967460; called by muse, mutect2, varscan2
- MUC2 | chr11:1097287 del G | 3'Flank (DEL) | VAF 11/55 reads (20%) | called by mutect2, varscan2
